CCDI case PBCCSW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/d84c0d1b-9858-4287-8909-3161fe6d282e

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Solitary fibrous tumor: ICD-O-3 morphology code: 8815/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.8 years (6,120 days).

Biospecimens (3 samples)
- Sample 0DOXGL: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DPH9X: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DPHAC: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
